Somatic mutation profile of tumor specimen TCGA-26-5139-01A (aliquot TCGA-26-5139-01A-01D-1486-08) from TCGA case TCGA-26-5139, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,782 days).
Specimen TCGA-26-5139-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a519407-6beb-4efe-8816-ccdcb0ce5341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-5139-10A (Blood Derived Normal), aliquot TCGA-26-5139-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb0a970c-3704-4a31-966c-f9a086ab1351

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Splice Site 2, 5'Flank 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC60 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs748209413, COSV59547456; called by muse, mutect2, varscan2
- CD70 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs757012345, COSV55565804; called by muse, mutect2, varscan2
- CDH18 | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs752178597, COSV56923211, COSV56955147; called by muse, mutect2, varscan2
- CEP131 | c.3002G>A p.R1001H (on ENST00000269392 / NM_001319228.2; = p.R998H on NM_014984.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs537921227, COSV53955942; called by muse, mutect2, varscan2
- CFAP97 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs759440454, COSV57112502; called by muse, mutect2, varscan2
- CHL1 | c.3163A>T p.N1055Y (on ENST00000397491 / NM_001253387.1; = p.N1071Y on NM_006614.4) | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV56604256; called by muse, mutect2, varscan2
- DSG4 | c.1934-1G>A p.X645_splice | Splice Site (SNP) | VAF 122/309 reads (39%) | catalogued as COSV57396787; called by muse, mutect2, varscan2
- EGFR | c.1883G>T p.C628F | Missense Mutation (SNP) | VAF 1897/2299 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51840469, COSV51851464; called by muse, mutect2, varscan2
- F8 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs782659883, COSV64277927, COSV64279041; called by muse, mutect2, varscan2
- FAT4 | c.9896G>A p.R3299H | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370611770, COSV58687349; called by muse, mutect2, varscan2
- FGD5 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs546389054, COSV53244199; called by muse, mutect2, varscan2
- LAS1L | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs919155075, COSV56708845; called by muse, mutect2, varscan2
- MUC5AC | c.16892C>T p.A5631V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.048); catalogued as rs375834347; called by muse, mutect2, varscan2
- MYOM2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs147661043, COSV50717399; called by muse, mutect2, varscan2
- OR4C46 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs137991158, COSV100061123; called by muse, mutect2
- PEAR1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1199224129, COSV52770905, COSV52771881; called by muse, mutect2, varscan2
- PIK3R1 | c.1748_1750del p.X583_splice (on ENST00000521381 / NM_181523.3; = p.X313_splice on NM_181504.4) | Splice Site (DEL) | VAF 40/116 reads (34%) | catalogued as rs1131692243; called by pindel, varscan2
- PNMA5 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs782149050, COSV62626169; called by muse, mutect2, varscan2
- PODNL1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); catalogued as rs147712582; called by mutect2, varscan2
- PREP | c.526G>A p.D176N (on ENST00000369110; = p.D242N on NM_002726.5) | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV64871807; called by muse, mutect2, varscan2
- PRKG2 | c.1669G>A p.V557I | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.094); catalogued as rs745754260, COSV52330825; called by muse, mutect2, varscan2
- PRR12 | c.2245G>A p.G749R (on ENST00000615927; = p.G1570R on NM_020719.3) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267033785, COSV69820577; called by muse, mutect2, varscan2
- RETN | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as rs566843624, COSV55569337; called by muse, mutect2, varscan2
- SI | c.4043C>T p.T1348M | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs192640245; called by muse, mutect2, varscan2
- SNAP25 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs535525064, COSV54770177; called by muse, mutect2, varscan2
- SOX3 | c.492G>C p.M164I | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65168603; called by muse, mutect2, varscan2
- STXBP5L | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs761722902, COSV56531753; called by muse, mutect2, varscan2
- TMPRSS6 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs1017672724, COSV100696262, COSV60978933; called by muse, mutect2, varscan2
- XDH | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65150914; called by muse, mutect2, varscan2
- YY1AP1 | c.383T>C p.F128S (on ENST00000295566 / NM_139118.2; = p.F51S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55124389; called by muse, mutect2, varscan2
- POLR2A | c.5634del p.T1880Pfs*? | Frame Shift Del (DEL) | VAF 59/159 reads (37%) | called by mutect2, pindel, varscan2
- RIC8B | c.127dup p.R43Kfs*6 | Frame Shift Ins (INS) | VAF 56/194 reads (29%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.3426C>T p.T1142= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs376977266; called by muse, mutect2, varscan2
- BTK | c.1386C>T p.G462= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs1555977842, COSV58123296; called by muse, mutect2, varscan2
- CCDC178 | c.288C>G p.V96= | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as COSV55793930; called by muse, mutect2, varscan2
- CD5L | c.471C>T p.N157= | Silent (SNP) | VAF 95/255 reads (37%) | catalogued as COSV63822951; called by muse, mutect2, varscan2
- FAM13B | c.2664G>A p.E888= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as rs1368057199, COSV50372601; called by muse, mutect2, varscan2
- KCNV1 | c.918C>T p.N306= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV52088732; called by muse, mutect2, varscan2
- KLHL40 | c.669C>T p.S223= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99825847; called by muse, varscan2
- MYT1L | c.576C>T p.D192= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs370624330, COSV67734896; called by muse, mutect2, varscan2
- NPRL2 | c.807C>T p.T269= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV51603878; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.561C>A p.I187= | Silent (SNP) | VAF 86/178 reads (48%) | catalogued as rs765836857, COSV57969932; called by muse, mutect2, varscan2
- PTPN6 | c.210G>A p.A70= | Silent (SNP) | VAF 76/183 reads (42%) | catalogued as rs782575533, COSV59686136; called by muse, mutect2, varscan2
- VPS72 | c.1035T>A p.P345= | Silent (SNP) | VAF 109/283 reads (39%) | called by muse, mutect2, varscan2
- WNK3 | c.1773A>G p.S591= | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV63615654; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504741 A>C | 5'Flank (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- PKD1L2 | n.4622G>C | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as rs760242510; called by muse, mutect2, varscan2
- TJP3 | c.-9-17C>T | Intron (SNP) | VAF 33/105 reads (31%) | catalogued as rs781274210, COSV53665265; called by muse, mutect2, varscan2
